Gene-level copy-number profile of tumor specimen ALCH-B38C-TTP1-A from ALCHEMIST case ALCH-B38C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,081 days).
Specimen ALCH-B38C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6e245952-ff9c-40f7-8863-d805bdf34df3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B38C-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/3e6a4dbc-b470-4c5b-80fb-4d812411c8b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 21,826; copy number 2: 35,041; copy number 3: 1,980; copy number 4: 5; copy number 5: 16; copy number 6: 3; copy number 7: 1; copy number 8: 4; copy number 13: 2; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,698,303–7,700,970, 2 genes (within-gene range 0–1): AL359881.2, AL359881.1.
- chr1:12,527,724–12,528,420, 1 gene: LINC02766.
- chr1:12,892,896–12,920,482, 2 genes (within-gene range 0–1): PRAMEF10, PRAMEF7.
- chr1:13,222,705–13,263,314, 3 genes: PRAMEF18, PRAMEF31P, PRAMEF5.
- chr1:13,279,125–13,392,629, 8 genes (within-gene range 0–8): RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17.
- chr2:24,825,610–24,826,717, 1 gene (within-gene range 0–1): AC012073.1.
- chr2:96,859,718–96,870,757, 1 gene: SEMA4C.
- chr2:232,406,844–232,421,461, 3 genes: ALPG, ECEL1P1, AC068134.2.
- chr2:241,734,715–241,735,498, 1 gene (within-gene range 0–1): AC114730.1.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr17:142,789–181,650, 1 gene: DOC2B.
- chr17:352,638–357,581, 2 genes (within-gene range 0–1): AC129507.2, AC129507.3.
- chr21:43,363,332–43,366,566, 1 gene: AP001046.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,915,153–143,976,734, 2 genes, copy number 5 (within-gene range 5–9): PLEC, MIR661.
- chr8:144,049,079–144,063,965, 3 genes, copy number 8–26: SMPD5, OPLAH, MIR6846.
- chr8:144,098,633–144,118,328, 3 genes, copy number 7–13: SHARPIN, MAF1, WDR97.
- chr9:137,447,570–137,459,334, 2 genes, copy number 8: NSMF, MIR7114.
- chr11:1,157,953–1,201,138, 1 gene, copy number 5: MUC5AC.
- chr16:1,148,224–1,221,771, 4 genes, copy number 5 (within-gene range 2–5): AC120498.8, CACNA1H, AC120498.3, AC120498.1.
- chr16:88,382,959–88,537,031, 4 genes, copy number 5: ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr17:41,054,498–41,060,114, 2 genes, copy number 5: KRTAP2-2, KRTAP2-3.
- chr19:3,607,247–3,613,930, 1 gene, copy number 5 (within-gene range 1–5): CACTIN-AS1.
- chr20:62,307,955–62,367,312, 3 genes, copy number 6 (within-gene range 2–11): LAMA5, MIR4758, LAMA5-AS1.
- chr20:62,388,632–62,407,285, 1 gene, copy number 5 (within-gene range 3–5): CABLES2.
- chr22:20,198,729–20,204,918, 1 gene, copy number 5: AC007663.2.

Autosomal genes at a single copy (total copy number 1): 19,203. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
